Somatic mutation profile of tumor specimen TCGA-75-6205-01A (aliquot TCGA-75-6205-01A-11D-1753-08) from TCGA case TCGA-75-6205, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-6205-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13342a45-cc05-4876-99a0-2b70116535c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-6205-10A (Blood Derived Normal), aliquot TCGA-75-6205-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59e1b937-0c64-4550-9cd6-5c2af40e85bc

The open-access MAF lists 45 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 34, Silent 7, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3009C>G p.Y1003* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | hotspot (GDC flag); catalogued as COSV59263576; called by muse, mutect2, varscan2
- ADCY8 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53913562; called by muse, varscan2
- AFDN | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100653470, COSV60047823; called by muse, mutect2, varscan2
- AKAP4 | c.2420T>C p.V807A | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV62074801; called by muse, mutect2
- AMOT | c.2260C>A p.Q754K (on ENST00000371959 / NM_001113490.1; = p.Q345K on NM_133265.3) | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV59065123; called by muse, mutect2
- ATG13 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.121); catalogued as COSV56320378; called by muse, mutect2
- CD2BP2 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs751813994, COSV59769105, COSV59769147; called by muse, mutect2, varscan2
- CEP43 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.194); catalogued as COSV62761105; called by muse, mutect2, varscan2
- DLGAP1 | c.1983A>T p.E661D | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV59814755; called by muse, mutect2
- FAM71B | c.1333C>T p.H445Y | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV57228302, COSV57229745; called by muse, mutect2
- FOXB2 | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100942319; called by muse, mutect2
- GIGYF1 | c.713C>G p.A238G | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV51943646; called by muse, mutect2
- IGLV1-44 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as rs917144369; called by muse, mutect2
- IQCB1 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60438191; called by muse, mutect2, varscan2
- KNL1 | c.1345C>G p.Q449E (on ENST00000346991 / NM_170589.5; = p.Q423E on NM_144508.5) | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV61156675; called by muse, mutect2
- MAGEE2 | c.560T>G p.I187S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV64897986; called by muse, mutect2, varscan2
- NLRC4 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs1317272776, COSV61593413; ClinVar: uncertain significance; called by muse, mutect2
- NTN4 | c.1600T>C p.S534P | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV59221052; called by muse, mutect2
- OR6C68 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.007); catalogued as COSV101110016; called by muse, mutect2
- PODN | c.944T>A p.L315Q (on ENST00000395871; = p.L267Q on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100439408; called by muse, mutect2
- PPP1R16B | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV55379520; called by muse, mutect2
- PSTK | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV64398710; called by muse, mutect2
- RIOK2 | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV51613371; called by muse, mutect2
- RLF | c.3167C>G p.T1056R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.505); catalogued as COSV65652216; called by muse, mutect2
- SYNDIG1L | c.343G>C p.V115L | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV59047837; called by muse, mutect2, varscan2
- TESK1 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52411578; called by muse, mutect2, varscan2
- TEX26 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as rs193234818, COSV66840133, COSV66841191; called by muse, mutect2, varscan2
- THAP6 | c.221G>C p.S74T | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61008725; called by muse, mutect2
- TOP1 | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63694647; called by muse, mutect2
- ZC3H12B | c.2336T>C p.M779T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59049388; called by muse, mutect2, varscan2
- ZNF347 | c.2001C>G p.H667Q | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.044); catalogued as COSV61969433; called by muse, mutect2, varscan2
- ZNF544 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1470858970, COSV99516893; called by muse, mutect2
- ZNF623 | c.1354A>T p.I452F | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV71697244; called by muse, mutect2
- ZNF678 | c.1528A>C p.I510L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV59384531; called by muse, mutect2, varscan2
- ZNF766 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.129); catalogued as COSV63009785; called by muse, mutect2, varscan2
- ZNF8 | c.800A>G p.N267S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.758); catalogued as rs202096304; called by muse, mutect2, varscan2
- SIRT7 | c.9del p.G5Vfs*2 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel
- SNX8 | c.737_739del p.A246_I247delinsV | In Frame Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- ADAMTS6 | c.639A>C p.T213= | Silent (SNP) | VAF 7/124 reads (6%) | catalogued as COSV66861385; called by muse, mutect2
- DENND5B | c.2634C>A p.L878= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV60904263, COSV60904580; called by muse, mutect2
- FILIP1 | c.2034T>C p.S678= | Silent (SNP) | VAF 16/274 reads (6%) | catalogued as rs767280732, COSV52733770; called by muse, mutect2
- KRIT1 | c.243T>A p.P81= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV60668937; called by muse, mutect2, varscan2
- MAST4 | c.1302C>T p.I434= (on ENST00000403625 / NM_001164664.2; = p.I245= on NM_015183.3) | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1561657497, COSV55130589; called by muse, mutect2
- OR51B5 | c.906T>C p.L302= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV56176472; called by muse, mutect2
- ZBTB3 | c.1323C>T p.A441= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV67361433; called by muse, mutect2, varscan2
